Somatic mutation profile of tumor specimen TCGA-KM-8443-01A (aliquot TCGA-KM-8443-01A-11D-2310-10) from TCGA case TCGA-KM-8443, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 58.0 years (21,183 days).
Specimen TCGA-KM-8443-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb99bfa2-5e5e-4252-8e51-9d6192e54e9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KM-8443-10A (Blood Derived Normal), aliquot TCGA-KM-8443-10A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49df76a3-9365-49c2-b110-5c188e762b9c

The open-access MAF lists 32 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 4, Frame Shift Ins 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL1 | c.935A>G p.Y312C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248519602, COSV100584833; called by muse, mutect2
- DRD3 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as rs749923013; called by muse, mutect2, varscan2
- EYA1 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 16/473 reads (3%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); catalogued as COSV100380519; called by muse, mutect2
- HSPG2 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754060584, COSV65978252; called by muse, mutect2, varscan2
- MUC4 | c.12584T>A p.V4195D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs747930807, COSV57764482; called by muse, mutect2
- RYR1 | c.4963C>T p.R1655C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as rs371777056; called by muse, mutect2, varscan2
- SACS | c.2747A>C p.K916T | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as rs747612620; called by muse, mutect2, varscan2
- SERPINB3 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.497); catalogued as rs377088096; called by muse, mutect2, varscan2
- SYT7 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567302490, COSV55658135; called by muse, mutect2, varscan2
- TIGIT | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369133784; called by mutect2, varscan2
- TOX | c.93T>A p.Y31* | Nonsense Mutation (SNP) | VAF 44/102 reads (43%) | catalogued as COSV100813195; called by muse, varscan2
- BSN | c.4705A>T p.T1569S | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CACNA2D1 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CHFR | c.908C>T p.T303I (on ENST00000432561 / NM_001161345.1; = p.T262I on NM_018223.2) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CLCN2 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- CSF2RB | c.2353G>T p.V785F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- GPBP1 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, varscan2
- GPBP1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, varscan2
- ICE1 | c.3837_3838dup p.K1280Ifs*10 | Frame Shift Ins (INS) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- LTN1 | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAP1B | c.4654G>A p.V1552M | Missense Mutation (SNP) | VAF 78/133 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MYO1F | c.938A>T p.D313V | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PTS | c.197C>G p.A66G | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RASA1 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RFX1 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SEMA6B | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SNX25 | c.2384G>A p.G795D | Missense Mutation (SNP) | VAF 141/314 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EBF1 | c.24C>A p.I8= | Silent (SNP) | VAF 42/164 reads (26%) | called by muse, mutect2, varscan2
- METTL25 | c.1704T>C p.C568= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99942809; called by muse, mutect2
- NBEAL2 | c.4182G>A p.G1394= | Silent (SNP) | VAF 68/132 reads (52%) | catalogued as rs746213780; called by muse, mutect2, varscan2
- TAS2R1 | c.786C>T p.F262= | Silent (SNP) | VAF 28/119 reads (24%) | called by muse, mutect2, varscan2
- MAGEB10 | c.*440C>T | 3'UTR (SNP) | VAF 30/111 reads (27%) | catalogued as rs754498551; called by muse, mutect2, varscan2
